Somatic mutation profile of cancer-model specimen HCM-CSHL-0858-C25-85M (3D Organoid, passage 8; aliquot HCM-CSHL-0858-C25-85M-01D-A85L-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0858-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 40.0 years (14,613 days).
Specimen HCM-CSHL-0858-C25-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23906b18-cae2-43df-bfd1-2d6aa28f0b3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0858-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0858-C25-10A-01D-A85L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d246de2e-a4cd-4cbe-a90e-28b3b761df00

The open-access MAF lists 75 somatic variants for this specimen: 51 protein-altering or splice-affecting, 20 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 20, Frame Shift Ins 4, Nonsense Mutation 2, Intron 2, 3'UTR 1, Nonstop Mutation 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F8 | c.6532C>T p.R2178C | Missense Mutation (SNP) | VAF 104/362 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852464, CM910148, COSV57704793; ClinVar: pathogenic; called by muse, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 214/402 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.1537G>A p.A513T | Missense Mutation (SNP) | VAF 310/441 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs761748692, COSV56854953, COSV56856905; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- ANOS1 | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 91/292 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs775708192, COSV52927509; called by muse, mutect2, varscan2
- CAGE1 | c.1381G>T p.E461* (on ENST00000512086; = p.E325* on NM_205864.3) | Nonsense Mutation (SNP) | VAF 247/247 reads (100%) | catalogued as rs576095436, COSV57076612; called by muse, mutect2, varscan2
- CDHR4 | c.1679A>G p.Y560C | Missense Mutation (SNP) | VAF 248/517 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.436); catalogued as rs1037122507; called by muse, mutect2, varscan2
- CDKN2A | c.170_171delinsT p.A57Vfs*89 | Frame Shift Del (DEL) | VAF 286/720 reads (40%) | catalogued as COSV58684998; called by pindel, varscan2*
- CIP2A | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 246/395 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as rs1164937135, COSV55418322; called by muse, mutect2, varscan2
- DMRT3 | c.551C>A p.A184E | Missense Mutation (SNP) | VAF 90/336 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.051); catalogued as rs778040412; called by muse, mutect2, varscan2
- FANCM | c.4271G>A p.R1424Q | Missense Mutation (SNP) | VAF 52/269 reads (19%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs1393856350, COSV57499649; called by muse, mutect2, varscan2
- FUNDC2 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 148/428 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs1557288293; called by muse, varscan2
- GABRA2 | c.1213G>T p.A405S | Missense Mutation (SNP) | VAF 298/620 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.077); catalogued as COSV100734587; called by muse, mutect2, varscan2
- HOXD11 | c.295G>A p.G99S | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.003); catalogued as rs1324538495; called by muse, mutect2, varscan2
- LAMA5 | c.9125G>A p.R3042H | Missense Mutation (SNP) | VAF 207/854 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as rs1184920313, COSV53373185; called by muse, mutect2, varscan2
- LETM1 | c.1795G>A p.V599M | Missense Mutation (SNP) | VAF 221/352 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as rs756578993; called by muse, mutect2, varscan2
- MPDZ | c.5114G>A p.R1705H | Missense Mutation (SNP) | VAF 161/467 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.419); catalogued as rs772699513; called by muse, mutect2, varscan2
- NPAP1 | c.3217G>A p.A1073T | Missense Mutation (SNP) | VAF 120/670 reads (18%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.025); catalogued as rs765231238; called by muse, mutect2, varscan2
- NUCKS1 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 113/584 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.782); catalogued as COSV65652578; called by muse, mutect2, varscan2
- OR2T10 | c.512C>A p.S171Y | Missense Mutation (SNP) | VAF 134/398 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV57895990; called by muse, mutect2, varscan2
- PDZRN3 | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 148/487 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as rs762027539, COSV55202644; called by muse, mutect2, varscan2
- RPL6 | c.713A>G p.E238G | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs776279399; called by mutect2, varscan2
- SCN2A | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 143/258 reads (55%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs773059303; called by muse, mutect2, varscan2
- SDK2 | c.4196G>A p.R1399H | Missense Mutation (SNP) | VAF 273/566 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs778845493; called by muse, varscan2
- WDR17 | c.3371G>T p.S1124I | Missense Mutation (SNP) | VAF 103/279 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV54573761; called by muse, mutect2, varscan2
- ZNF491 | c.1224G>T p.E408D | Missense Mutation (SNP) | VAF 297/586 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV60056798; called by muse, mutect2, varscan2
- AMER3 | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 122/580 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATG9B | c.1956T>G p.I652M | Missense Mutation (SNP) | VAF 228/515 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CENPVL3 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 264/791 reads (33%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL14A1 | c.3495dup p.A1166Cfs*14 | Frame Shift Ins (INS) | VAF 97/226 reads (43%) | called by mutect2, pindel, varscan2
- COL3A1 | c.3947G>C p.W1316S | Missense Mutation (SNP) | VAF 222/489 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- DNAH5 | c.5825A>G p.Y1942C | Missense Mutation (SNP) | VAF 216/459 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK7 | c.6336G>T p.K2112N (on ENST00000635253 / NM_001367561.1; = p.K2081N on NM_033407.3) | Missense Mutation (SNP) | VAF 126/433 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- GRM6 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 312/591 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- HCFC2 | c.1631A>G p.E544G | Missense Mutation (SNP) | VAF 99/189 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- KHDRBS2 | c.932A>T p.E311V | Missense Mutation (SNP) | VAF 99/227 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- MBD6 | c.1550C>T p.A517V | Missense Mutation (SNP) | VAF 327/328 reads (100%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- MPHOSPH10 | c.1517A>T p.K506I | Missense Mutation (SNP) | VAF 48/312 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MPHOSPH10 | c.1518A>T p.K506N | Missense Mutation (SNP) | VAF 48/311 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- NEK1 | c.2439G>C p.K813N | Missense Mutation (SNP) | VAF 117/365 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- NEUROG1 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 383/772 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); called by muse, varscan2
- NEUROG1 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 350/708 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); called by muse, varscan2
- NFAT5 | c.3684dup p.G1229Rfs*16 | Frame Shift Ins (INS) | VAF 255/505 reads (50%) | called by mutect2, pindel, varscan2
- PANX3 | c.357G>T p.L119F | Missense Mutation (SNP) | VAF 24/366 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.055); called by muse, mutect2
- PLCH2 | c.1025A>T p.N342I | Missense Mutation (SNP) | VAF 215/660 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PUM3 | c.1946A>G p.*649Wext*10 | Nonstop Mutation (SNP) | VAF 77/227 reads (34%) | called by muse, mutect2
- RND3 | c.631C>T p.Q211* | Nonsense Mutation (SNP) | VAF 282/635 reads (44%) | called by muse, mutect2, varscan2
- SEC24A | c.2454dup p.R819Sfs*15 | Frame Shift Ins (INS) | VAF 153/401 reads (38%) | called by mutect2, pindel, varscan2
- SLC25A16 | c.835A>G p.K279E | Missense Mutation (SNP) | VAF 77/226 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- TMEM101 | c.436G>T p.V146L | Missense Mutation (SNP) | VAF 212/844 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- UPF1 | c.256_257dup p.N86Kfs*9 | Frame Shift Ins (INS) | VAF 211/560 reads (38%) | called by mutect2, pindel, varscan2
- VMA21 | c.23C>A p.A8E | Missense Mutation (SNP) | VAF 129/351 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAMTS2 | c.2916C>T p.R972= | Silent (SNP) | VAF 403/862 reads (47%) | catalogued as rs201390812, COSV99284141; called by muse, mutect2, varscan2
- ADAMTS7 | c.2730C>T p.S910= | Silent (SNP) | VAF 197/382 reads (52%) | catalogued as rs529832761; called by muse, varscan2
- ADGRB1 | c.4089C>T p.P1363= | Silent (SNP) | VAF 229/452 reads (51%) | called by muse, mutect2, varscan2
- CPSF1 | c.2748C>T p.G916= | Silent (SNP) | VAF 390/390 reads (100%) | catalogued as rs782350591, COSV58233964; called by muse, mutect2, varscan2
- FEV | c.81C>T p.D27= | Silent (SNP) | VAF 92/413 reads (22%) | called by muse, mutect2, varscan2
- FLNB | c.270G>A p.E90= | Silent (SNP) | VAF 87/362 reads (24%) | catalogued as COSV55873500; called by muse, mutect2, varscan2
- IPO13 | c.948C>T p.G316= | Silent (SNP) | VAF 104/313 reads (33%) | catalogued as COSV64894793; called by muse, mutect2, varscan2
- KAT2A | c.657G>T p.G219= | Silent (SNP) | VAF 131/563 reads (23%) | called by muse, mutect2, varscan2
- KIR2DL4 | c.1035C>T p.C345= (on ENST00000396284; = p.C271= on NM_001080770.2) | Silent (SNP) | VAF 126/1238 reads (10%) | called by muse, mutect2, varscan2
- KMT2B | c.6150C>T p.S2050= | Silent (SNP) | VAF 406/868 reads (47%) | called by muse, mutect2, varscan2
- PAMR1 | c.306C>T p.T102= | Silent (SNP) | VAF 298/443 reads (67%) | catalogued as rs1201505613; called by muse, mutect2, varscan2
- PAPOLB | c.384C>T p.S128= | Silent (SNP) | VAF 147/547 reads (27%) | catalogued as rs377476980, COSV68203712; called by muse, mutect2, varscan2
- PCDHB3 | c.1398C>T p.P466= | Silent (SNP) | VAF 458/931 reads (49%) | catalogued as rs1554272453; called by muse, mutect2, varscan2
- POLR3C | c.114A>C p.V38= | Silent (SNP) | VAF 196/432 reads (45%) | called by muse, mutect2, varscan2
- SETD2 | c.6648C>T p.P2216= | Silent (SNP) | VAF 273/591 reads (46%) | called by muse, mutect2, varscan2
- SPATA3 | c.508C>T p.L170= | Silent (SNP) | VAF 190/740 reads (26%) | called by muse, varscan2
- SPECC1 | c.2902C>T p.L968= | Silent (SNP) | VAF 99/386 reads (26%) | called by muse, mutect2
- TARM1 | c.162G>A p.T54= (on ENST00000616041 / NM_001330650.1; = p.T46= on NM_001135686.3) | Silent (SNP) | VAF 754/1100 reads (69%) | catalogued as rs768953656; called by muse, mutect2, varscan2
- URB1 | c.3798C>T p.D1266= | Silent (SNP) | VAF 250/364 reads (69%) | catalogued as rs778096138; called by muse, varscan2
- ZNF738 | c.312A>T p.T104= | Silent (SNP) | VAF 52/254 reads (20%) | called by muse, mutect2, varscan2
- IGHE | chr14:105597768 G>A | 3'Flank (SNP) | VAF 64/410 reads (16%) | catalogued as rs1359966311; called by muse, mutect2
- PUM3 | c.*1G>T | 3'UTR (SNP) | VAF 74/216 reads (34%) | called by muse, mutect2
- SLC12A8 | c.737-136C>T | Intron (SNP) | VAF 100/326 reads (31%) | called by muse, varscan2
- ZNF655 | c.136+3329C>T | Intron (SNP) | VAF 219/463 reads (47%) | catalogued as rs370146835; called by muse, mutect2, varscan2
